Somatic mutation profile of tumor specimen 0DX0R1 from CCDI case PBCPRX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,180 days).
Specimen 0DX0R1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e856b343-7123-476f-ab92-0c0bd27b1417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74f91524-57c5-4107-8cba-12d693875629

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Splice Region 1, Intron 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SHANK1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs374644226, COSV53249194; called by muse, mutect2, varscan2
- SIPA1L1 | c.2185C>T p.R729* | Nonsense Mutation (SNP) | VAF 57/514 reads (11%) | catalogued as COSV62171084; called by muse, mutect2, varscan2
- FAM107A | c.327+5G>C | Splice Region (SNP) | VAF 35/308 reads (11%) | called by muse, mutect2, varscan2
- NRG1 | c.291G>A p.L97= (on ENST00000523534; = p.L244= on NM_013962.2) | Silent (SNP) | VAF 37/196 reads (19%) | called by muse, mutect2, varscan2
- PLSCR3 | c.144C>A p.G48= | Silent (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- HTR4 | c.1076+98C>T | Intron (SNP) | VAF 5/73 reads (7%) | catalogued as rs1223686088; called by muse, mutect2
